Somatic mutation profile of tumor specimen C3N-00661-01 (aliquot CPT0087570009) from CPTAC case C3N-00661, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 49.4 years (18,038 days).
Specimen C3N-00661-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37f17980-44ae-42ad-9309-4d92e945eb51.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00661-31 (Blood Derived Normal), aliquot CPT0087650002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84c63019-b79d-44aa-a32e-195cc2b5619b

The open-access MAF lists 57 somatic variants for this specimen: 41 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 13, Intron 3, Frame Shift Del 2, Nonsense Mutation 2, Splice Region 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC8 | c.2545G>A p.V849I | Missense Mutation (SNP) | VAF 53/389 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs770722134; called by muse, mutect2, varscan2
- AVIL | c.876C>G p.I292M | Missense Mutation (SNP) | VAF 2957/6780 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57680363; called by muse, mutect2, varscan2
- C6 | c.2101C>T p.R701W | Missense Mutation (SNP) | VAF 119/400 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.8); catalogued as rs199930769; called by muse, mutect2, varscan2
- CAVIN2 | c.1240G>A p.V414M | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.01); catalogued as COSV58423129, COSV58425038; called by muse, mutect2, varscan2
- COL6A5 | c.6722del p.E2241Gfs*5 (on ENST00000312481; = p.E2237Gfs*5 on NM_153264.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 91/342 reads (27%) | catalogued as COSV55193717; called by mutect2, pindel, varscan2
- CROT | c.652C>G p.L218V | Missense Mutation (SNP) | VAF 60/214 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as COSV100519505; called by muse, mutect2, varscan2
- DGKH | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 75/300 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs370149879; called by muse, mutect2, varscan2
- GRM4 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.593); catalogued as rs371898377; called by muse, mutect2, varscan2
- KCNK3 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57191875; called by muse, mutect2, varscan2
- KIF2B | c.539C>T p.T180I | Missense Mutation (SNP) | VAF 124/360 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs1350669205, COSV99274943; called by muse, mutect2, varscan2
- LAD1 | c.566C>T p.T189M | Missense Mutation (SNP) | VAF 15/213 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs370468944; called by muse, mutect2
- MYO7A | c.1871C>T p.T624M | Missense Mutation (SNP) | VAF 40/239 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs953533173; called by muse, mutect2, varscan2
- PRSS16 | c.211G>A p.V71M | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.575); catalogued as rs771996569, COSV57915773; called by muse, mutect2, varscan2
- RBM4 | c.869_886del p.A290_A295del | In Frame Del (DEL) | VAF 74/272 reads (27%) | catalogued as rs759186690; called by mutect2, pindel, varscan2
- RIMS2 | c.3979C>T p.R1327W | Missense Mutation (SNP) | VAF 73/303 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs370268038; called by muse, mutect2, varscan2
- RP1 | c.4925T>C p.I1642T | Missense Mutation (SNP) | VAF 118/480 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs1471875829; called by muse, mutect2, varscan2
- TRAT1 | c.349G>A p.V117I | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs149418284, COSV55469471; called by muse, mutect2, varscan2
- TREH | c.1499G>A p.R500Q | Missense Mutation (SNP) | VAF 56/197 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as rs782721212, COSV50621333, COSV50623872, COSV50624010; called by muse, mutect2, varscan2
- TRIB3 | c.100C>T p.R34* | Nonsense Mutation (SNP) | VAF 44/484 reads (9%) | catalogued as rs1404852588; called by muse, mutect2
- TTN | c.44648G>A p.R14883H (on ENST00000591111; = p.R7459H on NM_003319.4) | Missense Mutation (SNP) | VAF 62/245 reads (25%) | PolyPhen probably damaging (0.998); catalogued as rs757390152; called by muse, mutect2, varscan2
- AMBN | c.733C>A p.P245T | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.027); called by muse, mutect2
- CHPF | c.1564G>A p.A522T | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.908); called by muse, mutect2
- CNKSR2 | c.520-3_524delinsTTTTTTTT p.X174_splice | Splice Site (ONP) | VAF 5/58 reads (9%) | called by mutect2*, pindel
- DAND5 | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM171B | c.98A>T p.E33V | Missense Mutation (SNP) | VAF 103/338 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- GFY | c.280C>T p.R94* | Nonsense Mutation (SNP) | VAF 99/382 reads (26%) | called by muse, mutect2, varscan2
- KASH5 | c.1678C>T p.P560S | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KLK11 | c.677G>A p.G226E (on ENST00000594768 / NM_144947.3; = p.G194E on NM_006853.3) | Missense Mutation (SNP) | VAF 61/237 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MARS1 | c.2387G>C p.G796A | Missense Mutation (SNP) | VAF 1857/1948 reads (95%) | SIFT deleterious (0); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- MDM2 | c.1150A>C p.N384H | Missense Mutation (SNP) | VAF 3917/7294 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- MN1 | c.2186_2202del p.R729Lfs*56 | Frame Shift Del (DEL) | VAF 30/148 reads (20%) | called by mutect2, pindel, varscan2
- MROH2B | c.1531G>T p.A511S | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- RAI1 | c.3680C>T p.A1227V | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC34A2 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 50/303 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SORBS2 | c.3094C>A p.P1032T (on ENST00000284776 / NM_021069.5; = p.P598T on NM_003603.6) | Missense Mutation (SNP) | VAF 17/274 reads (6%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.972); called by muse, mutect2
- TFAP2C | c.905T>A p.L302Q | Missense Mutation (SNP) | VAF 137/558 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPM8 | c.628G>T p.V210L | Missense Mutation (SNP) | VAF 24/522 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.07); called by muse, mutect2
- TRPV5 | c.351T>A p.G117= | Splice Region (SNP) | VAF 27/101 reads (27%) | called by muse, mutect2, varscan2
- UTRN | c.1148C>T p.S383L | Missense Mutation (SNP) | VAF 50/241 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.287); called by muse, mutect2
- WDR97 | c.3463A>G p.T1155A | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNF219 | c.637G>T p.G213W | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ANKRD30A | c.2640C>T p.F880= (on ENST00000611781; = p.F824= on NM_052997.2) | Silent (SNP) | VAF 130/337 reads (39%) | catalogued as rs562184589, COSV100654471, COSV64606439; called by muse, mutect2, varscan2
- EXD1 | c.309G>A p.V103= | Silent (SNP) | VAF 65/307 reads (21%) | called by muse, mutect2, varscan2
- HPSE2 | c.942C>T p.I314= | Silent (SNP) | VAF 126/260 reads (48%) | catalogued as rs142810016, COSV65187751; called by muse, mutect2, varscan2
- OBSCN | c.9876G>A p.T3292= | Silent (SNP) | VAF 16/216 reads (7%) | catalogued as rs1338511116, COSV99484428; called by muse, mutect2
- PRICKLE2 | c.234G>A p.R78= (on ENST00000295902; = p.R22= on NM_198859.4) | Silent (SNP) | VAF 51/457 reads (11%) | catalogued as rs1270396956; called by muse, mutect2, varscan2
- PTPN6 | c.72C>T p.H24= | Silent (SNP) | VAF 113/544 reads (21%) | catalogued as rs782258923, COSV59684335; called by muse, mutect2, varscan2
- RALGAPA1 | c.4596G>A p.Q1532= | Silent (SNP) | VAF 22/119 reads (18%) | called by muse, mutect2, varscan2
- S1PR4 | c.381C>T p.T127= | Silent (SNP) | VAF 26/142 reads (18%) | catalogued as rs146518062; called by muse, mutect2, varscan2
- SV2B | c.1329G>A p.T443= | Silent (SNP) | VAF 24/112 reads (21%) | catalogued as rs780694074, COSV57703139; called by muse, varscan2
- TAF1 | c.1947G>A p.Q649= (on ENST00000373790 / NM_138923.4; = p.Q670= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/154 reads (8%) | called by muse, mutect2
- THADA | c.2586G>A p.P862= | Silent (SNP) | VAF 13/356 reads (4%) | catalogued as rs1364339808; called by muse, mutect2
- TIMP2 | c.552C>T p.N184= | Silent (SNP) | VAF 119/433 reads (27%) | catalogued as rs373804430; called by muse, mutect2, varscan2
- WSCD2 | c.315C>T p.G105= | Silent (SNP) | VAF 63/185 reads (34%) | catalogued as rs902928991; called by muse, mutect2, varscan2
- COL1A2 | c.2295+32A>G | Intron (SNP) | VAF 69/434 reads (16%) | called by muse, mutect2, varscan2
- GYS2 | c.1646-44G>A | Intron (SNP) | VAF 85/243 reads (35%) | called by muse, mutect2, varscan2
- TULP2 | c.1447+27G>T | Intron (SNP) | VAF 83/291 reads (29%) | called by muse, mutect2, varscan2
